Somatic mutation profile of tumor specimen TARGET-20-PARUWX-04A (aliquot TARGET-20-PARUWX-04A-01D) from TARGET case TARGET-20-PARUWX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,049 days).
Specimen TARGET-20-PARUWX-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a260934-70f2-4f85-969d-1c26dee48985.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUWX-14A (Bone Marrow Normal), aliquot TARGET-20-PARUWX-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5de82b0d-8ead-4811-889d-852314faf16a

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF469 | c.2103G>T p.G701= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
